Somatic mutation profile of tumor specimen C3L-06217-02 (aliquot CPT0456270006) from CPTAC case C3L-06217, project CPTAC-3 (Skin — Nevi and Melanomas). Sex at birth: female; Vital status: Alive; Primary diagnosis: Malignant melanoma, NOS; Tissue or organ of origin: Skin, NOS; AJCC pathologic stage: Stage IIIB; Age at diagnosis: 43.7 years (15,954 days).
Specimen C3L-06217-02: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Biospecimen anatomic site: Lymph Node; Preservation method: Snap Frozen.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 4ea1dee6-6fa8-4d16-8607-96f6c7d92a15.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen C3L-06217-31 (Blood Derived Normal), aliquot CPT0456410003; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/e44b928d-ec3f-4d56-b15e-0410f5c2e1d1

The open-access MAF lists 99 somatic variants for this specimen: 69 protein-altering or splice-affecting, 29 silent, 1 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 62, Silent 29, Nonsense Mutation 6, Splice Region 1, Intron 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- PHEX | c.1699C>T p.R567* | Nonsense Mutation (SNP) | VAF 48/489 reads (10%) | catalogued as rs137853271, CM060430; ClinVar: pathogenic; called by muse, mutect2
- AC136428.1 | c.73G>A p.E25K | Missense Mutation (SNP) | VAF 56/614 reads (9%) | SIFT deleterious, low confidence (0.02); PolyPhen probably damaging (0.976); catalogued as rs762523464; called by muse, mutect2
- ADGRB3 | c.4253G>A p.R1418Q | Missense Mutation (SNP) | VAF 11/168 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as rs1046244884, COSV53245112; called by muse, mutect2
- BRPF3 | c.1541G>A p.R514Q | Missense Mutation (SNP) | VAF 57/441 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as rs777000359; called by muse, mutect2, varscan2
- C9 | c.461G>A p.R154Q | Missense Mutation (SNP) | VAF 36/344 reads (10%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.953); catalogued as rs368001255, COSV99661547; called by muse, mutect2, varscan2
- CACNA2D3 | c.805G>A p.G269R | Missense Mutation (SNP) | VAF 46/513 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.985); catalogued as COSV55515101, COSV99878481; called by muse, mutect2
- CNTNAP4 | c.3026C>T p.S1009F | Missense Mutation (SNP) | VAF 17/100 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.969); catalogued as COSV56702461; called by muse, mutect2, varscan2
- CORO1C | c.1166C>T p.S389F | Missense Mutation (SNP) | VAF 40/388 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.984); catalogued as COSV54597281; called by muse, mutect2
- ELFN2 | c.1145C>T p.P382L | Missense Mutation (SNP) | VAF 60/438 reads (14%) | SIFT tolerated (0.26); PolyPhen benign (0.003); catalogued as COSV101297570, COSV68745145; called by muse, mutect2, varscan2
- FCRLB | c.971C>T p.S324L | Missense Mutation (SNP) | VAF 68/510 reads (13%) | SIFT tolerated (0.13); PolyPhen benign (0); catalogued as COSV61060487; called by muse, mutect2, varscan2
- FLG2 | c.3797G>A p.R1266K | Missense Mutation (SNP) | VAF 61/532 reads (11%) | SIFT tolerated (0.85); PolyPhen benign (0.042); catalogued as rs1325659183; called by muse, mutect2, varscan2
- FLNB | c.2779G>A p.D927N | Missense Mutation (SNP) | VAF 39/380 reads (10%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as rs764553857; called by muse, mutect2
- FUNDC1 | c.23C>T p.P8L | Missense Mutation (SNP) | VAF 51/509 reads (10%) | SIFT tolerated (0.43); PolyPhen benign (0.027); catalogued as rs1363362264; called by muse, mutect2, varscan2
- GABRB2 | c.1181C>T p.S394F | Missense Mutation (SNP) | VAF 24/202 reads (12%) | SIFT deleterious (0.05); PolyPhen benign (0.021); catalogued as COSV50905225; called by muse, mutect2, varscan2
- GIMAP8 | c.1018G>A p.D340N | Missense Mutation (SNP) | VAF 28/310 reads (9%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.979); catalogued as COSV100217309; called by muse, mutect2
- KCNA3 | c.1720G>A p.D574N | Missense Mutation (SNP) | VAF 28/286 reads (10%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.211); catalogued as COSV63902063; called by muse, mutect2
- KCNJ12 | c.1121C>T p.S374F | Missense Mutation (SNP) | VAF 72/960 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.932); catalogued as rs1555562933, COSV59166180; called by muse, mutect2
- KRT71 | c.907G>A p.E303K | Missense Mutation (SNP) | VAF 53/284 reads (19%) | SIFT deleterious (0.02); PolyPhen benign (0.166); catalogued as rs778601047, COSV57288926; called by muse, mutect2, varscan2
- MLYCD | c.1109C>T p.P370L | Missense Mutation (SNP) | VAF 59/482 reads (12%) | SIFT tolerated (0.06); PolyPhen benign (0.173); catalogued as rs759839871; called by muse, mutect2, varscan2
- MXRA5 | c.2576C>T p.S859F | Missense Mutation (SNP) | VAF 59/540 reads (11%) | SIFT deleterious (0.03); PolyPhen benign (0.038); catalogued as COSV54224676; called by muse, mutect2, varscan2
- MYT1 | c.901G>A p.E301K | Missense Mutation (SNP) | VAF 106/858 reads (12%) | SIFT tolerated (0.31); PolyPhen benign (0.043); catalogued as rs767969496, COSV60505959; called by muse, varscan2
- NWD1 | c.1638G>T p.W546C | Missense Mutation (SNP) | VAF 52/556 reads (9%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.998); catalogued as COSV60342228, COSV60346186; called by muse, mutect2
- OR11H6 | c.739C>T p.P247S | Missense Mutation (SNP) | VAF 36/382 reads (9%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.859); catalogued as COSV59644287; called by muse, mutect2
- OR4C6 | c.844C>T p.P282S | Missense Mutation (SNP) | VAF 38/466 reads (8%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.323); catalogued as COSV58604690, COSV58606437; called by muse, mutect2
- OR5T1 | c.460G>A p.V154M | Missense Mutation (SNP) | VAF 62/723 reads (9%) | SIFT tolerated (0.05); PolyPhen benign (0.417); catalogued as rs780858958; called by muse, mutect2
- PRSS36 | c.2243G>A p.G748E | Missense Mutation (SNP) | VAF 54/410 reads (13%) | SIFT tolerated (0.12); PolyPhen probably damaging (1); catalogued as rs1221316874; called by muse, mutect2, varscan2
- RBM6 | c.2698C>T p.P900S | Missense Mutation (SNP) | VAF 24/324 reads (7%) | SIFT tolerated (0.25); PolyPhen probably damaging (0.996); catalogued as COSV56480056; called by muse, mutect2
- RP1L1 | c.2875G>A p.E959K | Missense Mutation (SNP) | VAF 70/515 reads (14%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.865); catalogued as rs780471247, COSV101223761; called by muse, mutect2, varscan2
- RTTN | c.2193T>G p.D731E | Missense Mutation (SNP) | VAF 12/276 reads (4%) | SIFT tolerated (0.4); PolyPhen benign (0.069); catalogued as COSV55341318; called by muse, mutect2
- SLC22A2 | c.1412C>T p.S471F | Missense Mutation (SNP) | VAF 31/456 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as COSV65266702; called by muse, mutect2
- SLC45A3 | c.350C>T p.P117L | Missense Mutation (SNP) | VAF 68/555 reads (12%) | SIFT tolerated (0.26); PolyPhen benign (0.015); catalogued as rs1264881379; called by muse, mutect2, varscan2
- TBX18 | c.1298C>T p.S433F | Missense Mutation (SNP) | VAF 59/454 reads (13%) | SIFT tolerated (0.71); PolyPhen benign (0.347); catalogued as COSV100858502, COSV63736128; called by muse, mutect2, varscan2
- TRPV2 | c.11C>T p.P4L | Missense Mutation (SNP) | VAF 21/192 reads (11%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.007); catalogued as rs1356821312; called by muse, mutect2, varscan2
- WDTC1 | c.944C>T p.S315L | Missense Mutation (SNP) | VAF 33/350 reads (9%) | SIFT tolerated (0.43); PolyPhen benign (0.001); catalogued as rs267598533, COSV100089137; called by muse, mutect2
- ZFP62 | c.1399C>T p.H467Y (on ENST00000502412 / NM_001377944.1; = p.H434Y on NM_152283.5 and 5 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 43/396 reads (11%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as COSV63091112; called by muse, mutect2, varscan2
- ZNF470 | c.1163G>A p.R388Q | Missense Mutation (SNP) | VAF 43/402 reads (11%) | SIFT deleterious (0.02); PolyPhen benign (0.085); catalogued as rs886800028, COSV57969939; called by muse, mutect2, varscan2
- AP3B2 | c.2666C>T p.S889F (on ENST00000261722; = p.S883F on NM_004644.5) | Missense Mutation (SNP) | VAF 45/345 reads (13%) | SIFT tolerated (0.18); PolyPhen benign (0.341); called by muse, mutect2, varscan2
- ARID2 | c.641T>G p.L214* | Nonsense Mutation (SNP) | VAF 19/181 reads (10%) | called by muse, mutect2, varscan2
- ARVCF | c.589G>A p.D197N | Missense Mutation (SNP) | VAF 74/629 reads (12%) | SIFT tolerated (0.5); PolyPhen benign (0.014); called by muse, mutect2, varscan2
- CA1 | c.707G>C p.G236A | Missense Mutation (SNP) | VAF 39/344 reads (11%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.924); called by muse, mutect2, varscan2
- CFAP47 | c.9103G>A p.D3035N | Missense Mutation (SNP) | VAF 39/330 reads (12%) | SIFT tolerated (0.14); PolyPhen benign (0.216); called by muse, mutect2, varscan2
- CP | c.2229G>A p.W743* | Nonsense Mutation (SNP) | VAF 42/472 reads (9%) | called by muse, mutect2
- DNAH14 | c.92G>A p.G31E | Missense Mutation (SNP) | VAF 35/375 reads (9%) | called by muse, mutect2
- FNTA | c.478G>A p.E160K | Missense Mutation (SNP) | VAF 20/352 reads (6%) | SIFT tolerated (0.22); PolyPhen benign (0.092); called by muse, mutect2
- FREM2 | c.5659C>T p.P1887S | Missense Mutation (SNP) | VAF 40/262 reads (15%) | SIFT tolerated (0.07); PolyPhen benign (0.02); called by muse, mutect2, varscan2
- GEMIN5 | c.1993C>T p.Q665* | Nonsense Mutation (SNP) | VAF 36/276 reads (13%) | called by mutect2, varscan2
- GRM7 | c.791C>T p.T264I | Missense Mutation (SNP) | VAF 37/359 reads (10%) | SIFT tolerated (0.27); PolyPhen benign (0.049); called by muse, mutect2, varscan2
- IGHV1-58 | c.134G>A p.G45E | Missense Mutation (SNP) | VAF 49/408 reads (12%) | SIFT deleterious (0); PolyPhen possibly damaging (0.705); called by muse, mutect2, varscan2
- ILDR1 | c.799C>T p.L267F (on ENST00000344209 / NM_001199799.2; = p.L223F on NM_175924.4) | Missense Mutation (SNP) | VAF 29/324 reads (9%) | SIFT tolerated (0.11); PolyPhen benign (0); called by muse, mutect2
- IQCM | c.269C>T p.P90L | Missense Mutation (SNP) | VAF 49/464 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.932); called by muse, mutect2, varscan2
- IQGAP2 | c.381G>A p.K127= | Splice Region (SNP) | VAF 34/287 reads (12%) | called by muse, mutect2, varscan2
- LPA | c.3269C>T p.P1090L | Missense Mutation (SNP) | VAF 21/257 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.922); called by muse, mutect2
- LRRC25 | c.839C>T p.S280F | Missense Mutation (SNP) | VAF 58/360 reads (16%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.867); called by muse, mutect2, varscan2
- NPSR1 | c.614C>T p.S205F | Missense Mutation (SNP) | VAF 59/358 reads (16%) | SIFT tolerated (0.71); PolyPhen benign (0.179); called by muse, mutect2, varscan2
- OGDHL | c.2089C>T p.Q697* | Nonsense Mutation (SNP) | VAF 30/437 reads (7%) | called by muse, mutect2
- OR3A2 | c.803A>G p.Y268C | Missense Mutation (SNP) | VAF 39/300 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); called by muse, mutect2, varscan2
- OTUD4 | c.1303C>T p.R435* (on ENST00000447906 / NM_001366057.1; = p.R370* on NM_001102653.1) | Nonsense Mutation (SNP) | VAF 35/266 reads (13%) | called by muse, mutect2, varscan2
- PARD6B | c.1093G>A p.E365K | Missense Mutation (SNP) | VAF 30/263 reads (11%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.978); called by muse, mutect2, varscan2
- PCDHGA3 | c.157G>A p.G53R | Missense Mutation (SNP) | VAF 70/488 reads (14%) | SIFT deleterious, low confidence (0.01); PolyPhen possibly damaging (0.58); called by muse, mutect2, varscan2
- PLA1A | c.697G>A p.D233N | Missense Mutation (SNP) | VAF 51/439 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.966); called by muse, mutect2, varscan2
- PRDM15 | c.2524T>G p.C842G | Missense Mutation (SNP) | VAF 46/448 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2
- RLF | c.704C>T p.S235L | Missense Mutation (SNP) | VAF 44/456 reads (10%) | SIFT deleterious (0.01); PolyPhen benign (0.01); called by muse, mutect2
- SRRT | c.1559A>G p.D520G | Missense Mutation (SNP) | VAF 63/449 reads (14%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.984); called by muse, mutect2, varscan2
- TGFBR2 | c.1462A>G p.K488E | Missense Mutation (SNP) | VAF 47/485 reads (10%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.983); called by muse, mutect2
- THOC2 | c.1379T>G p.M460R | Missense Mutation (SNP) | VAF 26/249 reads (10%) | SIFT deleterious (0); PolyPhen possibly damaging (0.658); called by muse, mutect2, varscan2
- TMEM242 | c.373C>T p.P125S | Missense Mutation (SNP) | VAF 35/317 reads (11%) | SIFT tolerated (0.05); PolyPhen benign (0.03); called by muse, mutect2, varscan2
- TRAF3 | c.1616C>T p.A539V | Missense Mutation (SNP) | VAF 45/448 reads (10%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.593); called by muse, mutect2
- TUT1 | c.2248T>C p.S750P | Missense Mutation (SNP) | VAF 53/509 reads (10%) | SIFT tolerated (0.26); PolyPhen benign (0); called by muse, varscan2
- TXNDC16 | c.2071C>T p.L691F | Missense Mutation (SNP) | VAF 47/480 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2
- AHNAK2 | c.12612C>T p.G4204= | Silent (SNP) | VAF 86/568 reads (15%) | catalogued as rs1215367990, COSV60911240; called by muse, mutect2, varscan2
- ANKMY2 | c.478T>C p.L160= | Silent (SNP) | VAF 50/444 reads (11%) | catalogued as rs558909882; called by muse, mutect2, varscan2
- ARSG | c.729C>T p.L243= | Silent (SNP) | VAF 27/312 reads (9%) | called by muse, mutect2
- ART3 | c.705G>A p.Q235= | Silent (SNP) | VAF 39/394 reads (10%) | called by muse, mutect2, varscan2
- CCDC58 | c.18C>T p.G6= | Silent (SNP) | VAF 70/464 reads (15%) | catalogued as rs567371879, COSV51658718; called by muse, mutect2, varscan2
- CFAP46 | c.7185G>A p.R2395= | Silent (SNP) | VAF 30/484 reads (6%) | called by muse, mutect2
- CIC | c.702C>T p.F234= | Silent (SNP) | VAF 57/360 reads (16%) | called by muse, mutect2, varscan2
- FBXO17 | c.771C>T p.S257= | Silent (SNP) | VAF 50/356 reads (14%) | called by muse, mutect2, varscan2
- FSHR | c.132C>T p.L44= | Silent (SNP) | VAF 30/280 reads (11%) | called by muse, mutect2, varscan2
- GPX5 | c.528C>T p.V176= | Silent (SNP) | VAF 57/543 reads (10%) | catalogued as COSV69079986; called by muse, mutect2, varscan2
- GRM7 | c.792C>T p.T264= | Silent (SNP) | VAF 37/361 reads (10%) | called by muse, mutect2, varscan2
- IMMT | c.1290C>T p.I430= | Silent (SNP) | VAF 57/563 reads (10%) | catalogued as rs769821477; called by muse, mutect2, varscan2
- IMPG1 | c.451C>T p.L151= | Silent (SNP) | VAF 40/446 reads (9%) | catalogued as rs1271040403, COSV64061770; called by muse, mutect2
- KIF21B | c.2403G>A p.L801= | Silent (SNP) | VAF 33/438 reads (8%) | called by muse, mutect2
- KRTAP4-4 | c.39G>A p.Q13= | Silent (SNP) | VAF 58/390 reads (15%) | called by muse, varscan2
- KRTAP5-10 | c.312T>C p.C104= | Silent (SNP) | VAF 18/158 reads (11%) | catalogued as rs1431536859; called by muse, mutect2
- MAGEC3 | c.381G>A p.Q127= | Silent (SNP) | VAF 77/590 reads (13%) | called by muse, mutect2, varscan2
- MAP2K7 | c.1140C>T p.I380= | Silent (SNP) | VAF 45/325 reads (14%) | catalogued as rs748848079; called by muse, mutect2, varscan2
- MIA2 | c.1425G>A p.K475= | Silent (SNP) | VAF 29/251 reads (12%) | catalogued as rs1281347284, COSV99696671; called by muse, mutect2, varscan2
- MLIP | c.1260C>T p.S420= | Silent (SNP) | VAF 44/352 reads (13%) | called by muse, mutect2, varscan2
- NPHS1 | c.3201C>T p.F1067= | Silent (SNP) | VAF 46/483 reads (10%) | catalogued as rs749058353, COSV62287667; ClinVar: likely benign; called by muse, mutect2
- OR5M3 | c.459G>A p.T153= | Silent (SNP) | VAF 54/469 reads (12%) | catalogued as rs1177460032, COSV56567013; called by muse, mutect2, varscan2
- PCDHGA3 | c.156G>A p.L52= | Silent (SNP) | VAF 71/490 reads (14%) | catalogued as rs1561487340; called by muse, mutect2, varscan2
- PDK2 | c.759C>T p.F253= | Silent (SNP) | VAF 34/320 reads (11%) | called by muse, mutect2, varscan2
- PRSS1 | c.411G>A p.T137= | Silent (SNP) | VAF 58/410 reads (14%) | catalogued as rs369013081, COSV61190980; called by muse, varscan2
- RAB44 | c.1686G>A p.R562= | Silent (SNP) | VAF 60/502 reads (12%) | called by muse, mutect2, varscan2
- SNX31 | c.627C>T p.S209= | Silent (SNP) | VAF 12/294 reads (4%) | catalogued as COSV61263835; called by muse, mutect2
- TTLL13P | c.195C>T p.V65= | Silent (SNP) | VAF 42/393 reads (11%) | called by muse, mutect2, varscan2
- TYRO3 | c.375C>T p.T125= | Silent (SNP) | VAF 33/173 reads (19%) | catalogued as rs987305034; called by muse, mutect2, varscan2
- UACA | c.79-2256dup | Intron (INS) | VAF 28/247 reads (11%) | called by mutect2, pindel, varscan2
